Gene-level copy-number profile of tumor specimen ALCH-B3XZ-TTP1-A from ALCHEMIST case ALCH-B3XZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,221 days).
Specimen ALCH-B3XZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aae106b6-7991-4837-9732-5560389e3345.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3XZ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/b7f33898-e117-4ab0-8dce-9e53ac50c5bd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 112; copy number 1: 2,204; copy number 2: 55,164; copy number 3: 800; copy number 4: 82; copy number 5: 15; copy number 6: 6; copy number 7: 3; copy number 10: 1; copy number 12: 1.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr1:20,664,014–20,732,837, 3 genes: KIF17, AL663074.2, SH2D5.
- chr2:44,934,055–44,968,762, 9 genes (within-gene range 0–2): AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1.
- chr3:46,668,995–46,710,886, 2 genes: ALS2CL, TMIE.
- chr3:47,818,005–47,818,128, 1 gene (within-gene range 0–1): AC026318.1.
- chr4:167,741,879–167,742,287, 1 gene: AC105148.1.
- chr5:45,890,216–45,895,970, 1 gene: AC122694.1.
- chr7:55,731,100–55,743,457, 5 genes: Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2.
- chr7:56,955,785–57,020,273, 3 genes: MIR4283-1, TNRC18P3, SLC29A4P1.
- chr7:102,456,238–102,478,907, 5 genes (within-gene range 0–2): ALKBH4, LRWD1, MIR5090, MIR4467, POLR2J.
- chr7:128,830,406–128,910,719, 5 genes (within-gene range 0–2): FLNC, FLNC-AS1, KCP, ATP6V1F, ATP6V1FNB.
- chr8:43,672,823–46,028,892, 3 genes: AC139365.2, AC139365.1, AC118650.1.
- chr9:40,767,870–40,806,344, 1 gene: AL353626.1.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr11:45,885,651–45,929,096, 5 genes: MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2.
- chr11:46,277,662–46,386,608, 5 genes: CREB3L1, DGKZ, MIR4688, MDK, CHRM4.
- chr11:73,307,235–73,397,474, 4 genes: AP002761.3, ARHGEF17, RELT, AP000763.4.
- chr12:137,411–182,399, 3 genes (within-gene range 0–2): AC026369.1, AC026369.2, AC007406.3.
- chr12:51,848,223–51,852,729, 1 gene: FIGNL2-DT.
- chr12:124,337,181–124,337,242, 1 gene (within-gene range 0–2): MIR6880.
- chr12:130,425,004–130,430,661, 1 gene (within-gene range 0–2): AC063926.3.
- chr14:102,501,676–102,555,826, 4 genes (within-gene range 0–2): RNU6-244P, ANKRD9, MIR4309, LINC02323.
- chr15:25,189,414–25,225,284, 20 genes (within-gene range 0–2): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:90,883,695–90,895,776, 1 gene: FES.
- chr16:81,106,533–81,106,639, 1 gene (within-gene range 0–1): RNU6-1191P.
- chr17:1,762,029–1,777,565, 1 gene: SERPINF1.
- chr17:18,951,625–18,954,149, 1 gene (within-gene range 0–1): AC090286.1.
- chr17:39,603,536–39,609,777, 1 gene: NEUROD2.
- chr17:39,728,496–39,730,532, 1 gene (within-gene range 0–1): MIEN1.
- chr17:63,477,061–63,498,380, 1 gene (within-gene range 0–2): ACE.
- chr18:37,273,706–37,306,333, 2 genes (within-gene range 0–2): AC090386.1, AC090386.2.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–2): AC018445.3.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr21:43,358,147–43,366,566, 2 genes: LINC01679, AP001046.1.
- chr21:45,981,769–46,005,050, 1 gene: COL6A1.
- chr22:21,354,563–21,451,463, 8 genes: LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2.
- chr22:50,274,979–50,307,646, 1 gene (within-gene range 0–2): PLXNB2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:60,281,444–60,546,660, 1 gene, copy number 6: AC244258.1.
- chr8:143,734,139–143,790,645, 2 genes, copy number 6 (within-gene range 2–6): IQANK1, AC105219.3.
- chr14:18,333,726–18,412,264, 3 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2.
- chr16:1,833,986–1,884,294, 3 genes, copy number 6 (within-gene range 2–6): MEIOB, AL031722.1, LINC00254.
- chr16:2,339,150–2,426,699, 1 gene, copy number 5 (within-gene range 2–5): ABCA17P.
- chr21:10,397,644–13,120,807, 13 genes, copy number 5: AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,446,601–43,479,534, 2 genes, copy number 10–12 (within-gene range 2–12): LINC00319, LINC00313.

Autosomal genes at a single copy (total copy number 1): 2,199. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
